Somatic mutation profile of tumor specimen ALCH-AC7N-TTP1-A (aliquot ALCH-AC7N-TTP1-A-1-0-D-A49J-36) from ALCHEMIST case ALCH-AC7N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 80.3 years (29,322 days).
Specimen ALCH-AC7N-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 894034bc-6e1f-4ca4-b8ca-3a957784b774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC7N-NB1-A (Blood Derived Normal), aliquot ALCH-AC7N-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f1f14f-35a9-43f1-920c-4926b6043663

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, In Frame Del 3, Frame Shift Del 2, RNA 2, Intron 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 1118/1817 reads (62%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- EYA1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 46/603 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs121909199, CM000145; ClinVar: likely benign / benign / uncertain significance / pathogenic; called by muse, mutect2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 58/145 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.3103C>A p.L1035M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as rs776704547; called by muse, mutect2, varscan2
- DST | c.12766G>C p.E4256Q (on ENST00000361203 / NM_001374722.1; = p.E1844Q on NM_015548.5) | Missense Mutation (SNP) | VAF 210/445 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.834); catalogued as rs758298929; called by muse, mutect2, varscan2
- EFNA4 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1179332137; called by muse, mutect2, varscan2
- GLT8D2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs967761878, COSV62562497; called by muse, mutect2
- GPR146 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs776341739; called by muse, mutect2, varscan2
- HMCN2 | c.14368C>T p.R4790C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs749060696, COSV56739624; called by muse, mutect2, varscan2
- LPA | c.2604-1G>T p.X868_splice | Splice Site (SNP) | VAF 48/1290 reads (4%) | catalogued as rs1287761737, COSV100306395; called by muse, mutect2
- PLCG2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 55/455 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV63870557; called by muse, mutect2, varscan2
- PSME4 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs957977256; called by muse, mutect2, varscan2
- TGIF2LX | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs756251143, COSV52213659, COSV52215155; called by muse, varscan2
- ZGRF1 | c.5633G>A p.R1878H | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771333461; called by muse, mutect2
- ARHGEF38 | c.220T>G p.C74G | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ARMCX4 | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- B3GALT4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 30/333 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- BCHE | c.946G>T p.V316L | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COPA | c.2692del p.A898Qfs*50 | Frame Shift Del (DEL) | VAF 21/126 reads (17%) | called by mutect2, pindel
- DLGAP1 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DUSP2 | c.605T>A p.V202D | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERV3-1 | c.573T>G p.D191E | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCN1 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDI1 | c.1066_1068del p.T356del | In Frame Del (DEL) | VAF 40/132 reads (30%) | called by pindel, varscan2
- GTF2IRD2B | c.2284C>T p.H762Y | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by mutect2, varscan2
- HNRNPA1 | c.1064-4T>G | Splice Region (SNP) | VAF 130/303 reads (43%) | called by muse, mutect2, varscan2
- KDM2B | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEB | c.4066G>T p.V1356F | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDZD8 | c.1902G>T p.K634N | Missense Mutation (SNP) | VAF 89/404 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- RB1 | c.460_462del p.K154del | In Frame Del (DEL) | VAF 20/99 reads (20%) | called by pindel, varscan2
- RBM46 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.261); called by muse, mutect2
- RIPK4 | c.1639G>T p.A547S (on ENST00000352483; = p.A499S on NM_020639.3) | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SLC7A9 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF4 | c.604_610del p.A202Cfs*2 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel
- TENM2 | c.2617T>C p.C873R (on ENST00000518659 / NM_001122679.2; = p.C641R on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TFCP2 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 60/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMEM9B | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 59/518 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF382 | c.1460C>G p.T487R | Missense Mutation (SNP) | VAF 22/607 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF747 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- AP3B1 | c.2481A>G p.V827= | Silent (SNP) | VAF 115/785 reads (15%) | catalogued as rs1223753374; called by muse, mutect2, varscan2
- CD163L1 | c.2334G>A p.A778= | Silent (SNP) | VAF 66/300 reads (22%) | catalogued as rs201306383, COSV58016488; called by muse, varscan2
- CLRN1 | c.246G>C p.R82= | Silent (SNP) | VAF 194/462 reads (42%) | called by muse, mutect2, varscan2
- EFNA4 | c.246C>T p.G82= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- FBXO41 | c.2262C>A p.G754= | Silent (SNP) | VAF 16/50 reads (32%) | called by mutect2, varscan2
- HIP1 | c.2004C>T p.I668= | Silent (SNP) | VAF 20/489 reads (4%) | catalogued as rs1332959578, COSV100417253; called by muse, mutect2
- NOTCH4 | c.5358G>C p.L1786= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- PLRG1 | c.27T>C p.S9= | Silent (SNP) | VAF 86/363 reads (24%) | catalogued as rs551201192; called by muse, mutect2, varscan2
- RASGRF2 | c.1194C>A p.L398= | Silent (SNP) | VAF 70/557 reads (13%) | called by muse, mutect2, varscan2
- RHOD | c.102G>A p.L34= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- RSPH4A | c.1905C>T p.F635= | Silent (SNP) | VAF 132/775 reads (17%) | catalogued as rs9387422; called by muse, mutect2, varscan2
- RUBCNL | c.279G>A p.S93= | Silent (SNP) | VAF 94/348 reads (27%) | catalogued as rs751354791; called by muse, mutect2, varscan2
- SLITRK1 | c.447C>T p.A149= | Silent (SNP) | VAF 257/918 reads (28%) | catalogued as rs778556094, COSV65674485; called by muse, mutect2, varscan2
- AC136759.1 | n.534C>T | RNA (SNP) | VAF 79/590 reads (13%) | called by muse, mutect2, varscan2
- GOLGA8K | c.48+103G>A | Intron (SNP) | VAF 35/245 reads (14%) | catalogued as rs1164818311; called by muse, mutect2, varscan2
- KCNC3 | c.*1274C>G | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- PPME1 | c.835-27A>G | Intron (SNP) | VAF 28/154 reads (18%) | called by muse, varscan2
- XIST | n.11075A>C | RNA (SNP) | VAF 41/364 reads (11%) | called by muse, mutect2, varscan2
